Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A5SK, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A5SK-01A (Primary Tumor).

[page 1 of 2]
Note: If you do not see "END OF PRINTED REPORT" at the bottom of the last page of the report **YOU DO NOT HAVE THE ENTIRE REPORT**. Please try printing it again.

DOB

CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Ordering Provider

Relevant
Information
Location

ICD-O-3

Carcinoma, hepatocellular NOS
w/solid variant 8170/3

Site: Liver, hepatic NOS
C22.0

gW 4/2/13

Copied To

Report Patient
Demographics
(for verification
purposes)

Name

Date of Birth

Sex: M

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description

A. Gallbladder

B. Segment 7- liver . wt 62 g

Clinical Information

Infectious patient: Yes, Hep C+ ve

Immunocompromised: NK

History of neoplasm: NK

Hepatitis C related cirrhosis; hypervascular lesion in segment 8

Diagnosis

A. Gallbladder;

- No pathologic diagnosis.

B. Segment 7, Liver:

- Well differentiated hepatocellular carcinoma, solid variant, involving deep margin.
- Chronic hepatitis C of mild activity.
- Cirrhosis.

[page 2 of 2]
Verified:

Gross Description

Received are specimens A to B. All requisitions and specimen containers are labelled with the patient's name, . The cassettes and AP identifiers are labelled with the Surgical Number

A. The specimen is received fresh and is subsequently placed into formalin and consists of an intact gallbladder measuring 9.5 x 4.5 x 3.0 cm. The serosal surface is slightly hemorrhagic, smooth, congested and glistening. The adventitial surface is congested and roughened. The cystic duct resection margin is identified and is patent. The cystic duct lymph node is not identified. The lumen is filled with thick green mucinous bile (measuring about 20 ml). Also thick partially solidified bile flakes are identified attached to the mucosal surface of the fundus. The mucosal surface is green and slightly

velvety. The wall thickness of the gallbladder measures 0.1 cm. Specimen is serially sectioned and representative sections are submitted in A1 including cyst duct resection margin and sections from neck, body and fundus.

B. The specimen is received fresh and is subsequently placed into formalin and consists of a portion of liver weighing 62 g and measuring 7.5 x 6.8 cm with a maximum thickness of 2.9 cm. The serosal surface of a liver has a grey purple and dark brown slightly roughened appearance. Serosal surface also appears slightly nodular. Resection margin of the liver is marked with blue dye. Specimen is serially sectioned. A light tan opaque nodule is identified on the cut surface of the specimen measuring 3.0 x 3.0 x 2.4 cm. This nodule grossly coming to within less than 0.1 cm of the blue inked resection margin as well as serosal surface.

The remaining cut surface of the liver has a light tan nodular appearance.

Sections are submitted as follows:

- B1-5 - Sections from the opaque nodule also including blue inked resection margin and the serosal surface
- B6, 7 - Sections from the remaining liver parenchyma.

Accession
Number
Encounter
Number
Patient Location

- END OF PRINTED REPORT -

Diagnostic Discrepancy		✓
HPV Discrepancy		✓
Other Malignancy History		✓
Early Synchronous Primary		✓

Source: NCI Genomic Data Commons file 93786587-7afd-43a0-b264-b3eb50a35e71 (TCGA-G3-A5SK.6FB76663-58FA-48DD-A0F8-136C975FE067.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).